Somatic mutation profile of tumor specimen 0DWRMV from CCDI case PBCPBW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Synovial sarcoma, spindle cell; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 10.8 years (3,949 days).
Specimen 0DWRMV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c741e6ec-b841-4b92-a463-ac1dd96f258f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWRMZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee7c6805-e286-426e-99f5-0cc91fb71315

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1204C>G p.R402G | Missense Mutation (SNP) | VAF 74/822 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV60124081; called by muse, mutect2
- CCDC39 | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 317/812 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs776770476; called by muse, mutect2, varscan2
- TMPRSS11B | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 300/711 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs759100973, COSV60293040; called by muse, mutect2, varscan2
- ABAT | c.1139A>T p.N380I | Missense Mutation (SNP) | VAF 106/611 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DCDC1 | c.4698A>T p.K1566N (on ENST00000597505 / NM_001367979.1; = p.K673N on NM_020869.3) | Missense Mutation (SNP) | VAF 335/847 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- NFATC4 | c.1781G>A p.S594N | Missense Mutation (SNP) | VAF 322/759 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- DYNC2I1 | c.2590C>T p.L864= | Silent (SNP) | VAF 57/1126 reads (5%) | catalogued as rs768915076; called by muse, mutect2
- TCHH | c.2325A>G p.E775= | Silent (SNP) | VAF 220/508 reads (43%) | called by muse, mutect2, varscan2
